CCDI case PBCNZE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1cc33ccf-cea4-4b41-b506-0e0e43ca8a6b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,572 days).

Biospecimens (3 samples)
- Sample 0DWD1P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWD24: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWD2C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
